Somatic mutation profile of tumor specimen TARGET-10-PAREIE-09A (aliquot TARGET-10-PAREIE-09A-01D) from TARGET case TARGET-10-PAREIE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.2 years (4,451 days).
Specimen TARGET-10-PAREIE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ca37957-05ce-4aca-aae3-9f53835d0012.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREIE-10A (Blood Derived Normal), aliquot TARGET-10-PAREIE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a5ab5e1-386a-48c3-a7a3-f2179f28c9e0

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, In Frame Del 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.845G>C p.R282P | Missense Mutation (SNP) | VAF 73/264 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs730882008, CM004344, COSV52689673, COSV52773873, COSV52969460, COSV53068318; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LONRF2 | c.922-1G>T p.X308_splice | Splice Site (SNP) | VAF 3/38 reads (8%) | catalogued as COSV66539737; called by muse, mutect2
- NRXN3 | c.1819G>A p.A607T (on ENST00000557594 / NM_001272020.2; = p.A1031T on NM_004796.6) | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as rs759711936, COSV55361471; called by muse, mutect2, varscan2
- SULF1 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs376825615, COSV52675587; called by muse, mutect2, varscan2
- ADAM19 | c.1713G>T p.K571N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- MMEL1 | c.83_85del p.G28_L29delinsV | In Frame Del (DEL) | VAF 6/39 reads (15%) | called by pindel, varscan2
- MYO5A | c.775T>G p.Y259D | Missense Mutation (SNP) | VAF 68/295 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHTN1 | c.244A>T p.S82C | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DIXDC1 | c.656+2799C>A | Intron (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
